Somatic mutation profile of tumor specimen TCGA-ZM-AA05-01A (aliquot TCGA-ZM-AA05-01A-12D-A435-10) from TCGA case TCGA-ZM-AA05, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 36.4 years (13,295 days).
Specimen TCGA-ZM-AA05-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbe2082b-0eec-4192-a994-3c8481102210.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA05-10A (Blood Derived Normal), aliquot TCGA-ZM-AA05-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24d96ba9-ef37-40c2-98a3-fffc258b88a2

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 19/300 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ATAD3C | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs202189170; called by muse, mutect2, varscan2
- ELOA2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1341972663; called by muse, mutect2, varscan2
- HOXD9 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs751672056, COSV50891747; called by muse, mutect2, varscan2
- ZC3H11A | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs774220377; called by muse, mutect2, varscan2
- ANK2 | c.4425A>C p.K1475N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2
- CDHR1 | c.1794G>C p.E598D | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, varscan2
- CREBBP | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DDX60 | c.4600G>A p.E1534K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP26 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OLFML3 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PCSK4 | c.582C>G p.S194R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.711); called by muse, mutect2
- RACGAP1 | c.665C>G p.T222S | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2
- TTC28 | c.3289G>C p.V1097L | Missense Mutation (SNP) | VAF 37/379 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); called by muse, mutect2
- ZMYM2 | c.2182A>T p.N728Y | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF880 | c.1292C>T p.T431I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2
- SH2B1 | c.1698C>T p.L566= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1417513073; called by muse, mutect2, varscan2
- SLC26A8 | c.690T>C p.S230= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- TECR | c.477C>A p.R159= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- RBFOX3 | c.936+74G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1024609511; called by muse, mutect2, varscan2
